Somatic mutation profile of tumor specimen TARGET-10-PAPCRD-09A (aliquot TARGET-10-PAPCRD-09A-01D) from TARGET case TARGET-10-PAPCRD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (933 days).
Specimen TARGET-10-PAPCRD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 036711ec-f46a-4175-8d42-a78f0c1f2da5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCRD-10A (Blood Derived Normal), aliquot TARGET-10-PAPCRD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dea3f678-5062-4fbc-96e1-7ddcc10c05b3

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GARNL3 | c.2390C>A p.S797* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV59231360; called by muse, mutect2
- KIAA1958 | c.636C>A p.Y212* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV61727785; called by muse, mutect2
- MFSD3 | c.826C>A p.H276N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as rs1353452904; called by muse, mutect2, varscan2
- RRP12 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs748890104; called by muse, mutect2, varscan2
- SOX9 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55422427; called by muse, mutect2
- ASIC4 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FANK1 | c.664C>A p.H222N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPN13 | c.7450C>A p.L2484M (on ENST00000411767 / NM_080683.3; = p.L2465M on NM_006264.3) | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.259); called by muse, mutect2
- SUPV3L1 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2
- ZBTB11 | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANK3 | c.6270C>T p.T2090= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
